TCGA case TCGA-XE-AAOB — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis; Tissue source site: University of Southern California. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7db75a66-3e9d-40e1-93c0-23f3630d6a9c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 27 years; Year of birth: 1981; Vital status: Dead; Days to death: 513 days (1.4 years); Year of death: 2010; Cause of death: Cancer Related; Cause of death source: Social Security Death Index.

Diagnoses (5)
1. Teratocarcinoma (the primary disease): ICD-O-3 morphology code: 9081/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 27.1 years (9,907 days); Year of diagnosis: 2008; Method of diagnosis: Orchiectomy; AJCC staging edition: 6th; AJCC clinical T: T1; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IS; AJCC pathologic T: T1; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage IS; IGCCCG stage: Intermediate Prognosis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 513 days (1.4 years); Ajcc serum tumor markers: S1.
   Pathology details: Intratubular germ cell neoplasia present: Yes; Lymphatic invasion present: No; Vascular invasion present: No.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: No; Timepoint category: Postoperative.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Teratocarcinoma), site: Lymph node, NOS. Age at diagnosis: 27.8 years (10,138 days); Days to diagnosis: 231 days; Prior treatment: Yes.
3. Metastasis of diagnosis 1 (Teratocarcinoma), site: Liver. Age at diagnosis: 28.3 years (10,339 days); Days to diagnosis: 432 days (1.2 years); Prior treatment: Yes.
4. Metastasis of diagnosis 1 (Teratocarcinoma), site: Lymph node, NOS. Age at diagnosis: 28.3 years (10,339 days); Days to diagnosis: 432 days (1.2 years); Prior treatment: Yes.
5. Metastasis of diagnosis 1 (Teratocarcinoma), site: Lung, NOS. Age at diagnosis: 28.3 years (10,339 days); Days to diagnosis: 432 days (1.2 years); Prior treatment: Yes.

Follow-up (5 entries)
- Day 231 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 231 days.
- Day 432 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 432 days (1.2 years).
- Day 432 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 432 days (1.2 years).
- Day 432 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 432 days (1.2 years).
- Days to follow up: 513 days (1.4 years); Disease response: With Tumor.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -17: Lactate Dehydrogenase 109; Alpha Fetoprotein 152; Human Chorionic Gonadotropin 479.
- Day 442: Lactate Dehydrogenase 338; Alpha Fetoprotein 0.6; Human Chorionic Gonadotropin 38014.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Fertility history: Did not attempt to reproduce; Undescended testis history: No.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-XE-AAOB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 660 mg.
  Slide TCGA-XE-AAOB-01A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-XE-AAOB-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-XE-AAOB-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; History hypospadias: No; Tumor status: With tumor; Cause of death: Testicular Germ Cell Tumor (TGCT).
- Stage record: AJCC pathologic tumor stage: IS; Igcccg stage: Intermediate.
- Primary pathology: Submitted tumor site: Testes; Testis tumor macroextent: Involves testis only; Intratubular germ cell neoplasm: Present; Lymphovascular invasion: No; Post orchi lymph node dissection: No; First treatment success: Progressive Tumor Mass and Tumor Markers.
- Primary pathology, Histology list, Histology 1: Histologic diagnosis: Non-Seminoma, Choriocarcinoma; Histologic diagnosis percent: 5.
- Primary pathology, Histology list, Histology 2: Histologic diagnosis: Non-Seminoma, Embryonal Carcinoma; Histologic diagnosis percent: 30.
- Primary pathology, Histology list, Histology 3: Histologic diagnosis: Non-Seminoma, Yolk Sac Tumor; Histologic diagnosis percent: 5.
- Primary pathology, Histology list, Histology 4: Histologic diagnosis: Non-Seminoma, Teratoma (Mature); Histologic diagnosis percent: 30.
- Primary pathology, Histology list, Histology 5: Histologic diagnosis: Non-Seminoma, Teratoma (Immature); Histologic diagnosis percent: 30.
- Primary pathology, Pre orchi serum marker info: Pre orchi LDH: 109; Pre orchi hcg: 479; Pre orchi afp: 152.1.
- Primary pathology, Post orchi serum marker info: Post orchi LDH: 338; Post orchi hcg: 38014; Post orchi afp: 0.6.
- Primary pathology, Molecular test result list: Molecular test result: Lactate Dehydrogenase (LDH) - Progressed; Molecular test result: Human Chorionic Gonadotropin (HCG) - Progressed; Molecular test result: Alpha Fetaprotein (AFP) - Normal.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 513 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 513 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 231 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-XE-AAOB-01A-11D-A434-01): tumor purity 0.37, ploidy 2.88, whole-genome doublings 1.
